Gene-level copy-number profile of tumor specimen TCGA-2G-AAFX-01A from TCGA case TCGA-2G-AAFX, project TCGA-TGCT (Testicular Germ Cell Tumors). Sex at birth: male; Vital status: Alive; Primary diagnosis: Seminoma, NOS; Tissue or organ of origin: Testis, NOS; AJCC pathologic stage: Stage I; Age at diagnosis: 57.1 years (20,855 days).
Specimen TCGA-2G-AAFX-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file 09bdbfba-470c-4a51-a660-ae835a7ded5d.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator TCGA-2G-AAFX-10A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,722 have no estimate.
https://portal.gdc.cancer.gov/files/58b9a8ee-794d-44a7-97ca-f53654f42bab

Most common (modal) total copy number across autosomal genes: 3 — above the diploid value of 2, consistent with a largely gained or genome-doubled tumor.
Genes by total copy number (all chromosomes): copy number 0: 18; copy number 1: 1,611; copy number 2: 21,490; copy number 3: 23,961; copy number 4: 8,289; copy number 5: 1,572; copy number 6: 1,456; copy number 7: 41; copy number 13: 37; copy number 15: 224; copy number 16: 75; copy number 19: 2; copy number 20: 11; copy number 25: 11; copy number 26: 61; copy number 28: 42.

Homozygous deletions (total copy number 0; autosomes only): 18 genes in 3 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr5:17,528,669–17,625,959, 13 genes: TAF11L6, TAF11L7, AC233724.7, TAF11L8, TAF11L9, TAF11L10, AC233724.3, AC233724.6, TAF11L11, TAF11L12, H3P19, H3P20, H3P21.
- chr5:180,967,189–181,006,727, 4 genes: AC091874.2, AC091874.1, ARPP19P1, BTNL3.
- chr9:4,944,670–4,945,902, 1 gene: HNRNPA1P41.

Amplified relative to the modal value (total copy number ≥ 7, i.e. more than twice the modal value of 3; autosomes only): 504 genes in 5 contiguous regions (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr4:54,229,280–59,834,167, 92 genes, copy number 15–16 (within-gene range 3–16) (broad region; genes not listed).
- chr8:93,698,561–94,896,678, 41 genes, copy number 7 (within-gene range 6–7): CIBAR1, AC120053.1, AC010834.3, RBM12B, AC010834.1, RBM12B-AS1, AC010834.2, TMEM67, AC084346.1, MYL12AP1, PDP1, MIR378D2HG, MIR378D2, PSMA2P2, RPL34P18, AC105081.1, AP003351.1, CDH17, AP003478.1, GEM, RPS4XP10, RAD54B, FSBP, VIRMA, AC023632.5, AC023632.2, AC023632.1, AC023632.3, AC023632.4, AC108860.2, ESRP1, Metazoa_SRP, AC108860.1, AP005660.1, Y_RNA, DPY19L4, AP003692.1, INTS8, CCNE2, AC087752.4, AC087752.1.
- chr12:166,856–5,046,788, 120 genes, copy number 15 (within-gene range 2–15) (broad region; genes not listed).
- chr12:14,665,655–15,006,999, 15 genes, copy number 15 (within-gene range 6–15): AC010168.1, AC010168.2, H4-16, H2AJ, WBP11, C12orf60, SMCO3, AC007655.2, ART4, AC007655.1, MGP, ERP27, ARHGDIB, PDE6H, LINC01489.
- chr12:18,683,169–31,959,316, 236 genes, copy number 13–28 (within-gene range 2–28) (broad region; genes not listed).

Autosomal genes at a single copy (total copy number 1): 1,060. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
